Somatic mutation profile of tumor specimen 0DFMIP from CCDI case PBBSFK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (650 days).
Specimen 0DFMIP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e82c675-e841-4442-bdab-ff03abc09a8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFMIQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72b2f8fb-c21c-4eab-85c5-b6b7291b5b0a

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH8 | c.10414C>G p.Q3472E | Missense Mutation (SNP) | VAF 175/422 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59438950; called by muse, mutect2, varscan2
- KL | c.1313T>A p.I438N | Missense Mutation (SNP) | VAF 147/356 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PTPRG | c.3369G>T p.K1123N | Missense Mutation (SNP) | VAF 40/695 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.231); called by muse, mutect2
- THBS2 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 32/780 reads (4%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.665); called by muse, mutect2
- CCDC149 | c.63+17714C>A | Intron (SNP) | VAF 14/320 reads (4%) | catalogued as rs1341369251; called by muse, mutect2
- CCDC149 | c.63+17713T>G | Intron (SNP) | VAF 14/316 reads (4%) | called by muse, mutect2
- EEFSEC | chr3:128153420 G>A | 5'Flank (SNP) | VAF 115/230 reads (50%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- SLCO6A1 | c.1276+70T>C | Intron (SNP) | VAF 42/86 reads (49%) | called by mutect2, varscan2
